Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A026, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A026-01A (Primary Tumor).

Internal Sample IC

This is vascularized fatty connective tissue with an extensive, chronically granulating and recurrent inflammation with fibrosis, acute inflammatory activity, hemorrhage and fine foci of necrosis.

No evidence of specificity or malignancy.

This is a poorly differentiated adenocarcinoma of the rectum with a degree of pathological differentiation of G 3, with carcinomatous lymphangiosis, erosions/ulcerations of the inner tumor surface, accompanying peritumoral, chronic, recurrent inflammation with an acute purulent abscess-forming inflammatory flare, tumor infiltration of the rectal wall layers into the perirectal connective tissue (in I.), with similar tumor infiltrates and extensive peritumoral, chronically granulating and recurrent inflammation in the soft tissue of the sacral cavity (in III.), moderate chronic lymphadenitis of the tumor-free lymph nodes (0/15), tumor-free resection margins – aborally and orally – (in I.) and tumor-free plain section from the anastomosis ring (in II.).

The tumor spread of the rectal carcinoma, according to the available sections, corresponds to a tumor stage of p T 4, p N 0, M x, L 1 and at least R 1.

No evidence of carcinosis of the blood vessels.

The study result was discussed by telephone.

12+

ICD-0-3

Adenocarcinoma, NOS 8140/3

Site: Rectum C20.9 p 3/31/11

	☒	☒

Rmt 5/10/11

Source: NCI Genomic Data Commons file 46339cf8-6e8f-4aff-a37f-778a9073d860 (TCGA-AG-A026.800BF328-7F21-4BF0-95CA-D9092FC6B2D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).